Somatic mutation profile of tumor specimen HCM-CSHL-0180-C25-01A (aliquot HCM-CSHL-0180-C25-01A-11D-A79L-36) from HCMI case HCM-CSHL-0180-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.0 years (23,371 days).
Specimen HCM-CSHL-0180-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98b294df-fbfa-47bd-b1c2-94ac9fee4809.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0180-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0180-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d977d5af-a937-41d3-ba2c-703d4be72123

The open-access MAF lists 65 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 17, Intron 3, Nonsense Mutation 2, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 42/383 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455dup p.P153Afs*28 | Frame Shift Ins (INS) | VAF 48/440 reads (11%) | catalogued as rs730882019, COSV53468298, COSV99394349; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADCY1 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs1326557048, COSV52032152; called by muse, mutect2, varscan2
- ADRA1D | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 71/601 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs538270081, COSV65240389; called by muse, mutect2, varscan2
- AXL | c.1828C>T p.R610* (on ENST00000301178 / NM_021913.5; = p.R601* on NM_001699.6) | Nonsense Mutation (SNP) | VAF 45/401 reads (11%) | catalogued as rs758985963, COSV56566085; called by muse, mutect2, varscan2
- C7orf61 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 82/586 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as rs370137741; called by muse, mutect2, varscan2
- CACNA1F | c.5369G>A p.R1790H | Missense Mutation (SNP) | VAF 65/502 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs781946990, COSV59905762; called by muse, mutect2, varscan2
- CDK6 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV56006892; called by muse, mutect2, varscan2
- COL24A1 | c.2230G>A p.G744R | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65306064; called by muse, mutect2, varscan2
- FGFR3 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs769591617, COSV53404184; called by muse, mutect2, varscan2
- FOXL3 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 51/447 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72563063; called by muse, varscan2
- INSRR | c.2970T>G p.F990L | Missense Mutation (SNP) | VAF 72/487 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100947344; called by muse, mutect2, varscan2
- KCNF1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 71/508 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1313019497; called by muse, mutect2, varscan2
- KCNH4 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs751569305, COSV52920746; called by muse, mutect2, varscan2
- KHDRBS3 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 37/433 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs200509558, COSV63414522; called by muse, mutect2
- MGAT5B | c.1898G>A p.R633Q (on ENST00000569840 / NM_001199172.2; = p.R631Q on NM_144677.3) | Missense Mutation (SNP) | VAF 54/433 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56927723; called by muse, mutect2, varscan2
- MROH9 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1427137680; called by muse, mutect2
- NAPA | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 52/437 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs774144496; called by muse, mutect2, varscan2
- PLSCR2 | c.497C>A p.P166Q (on ENST00000497985 / NM_001199978.1; = p.P93Q on NM_020359.2) | Missense Mutation (SNP) | VAF 28/347 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100367854; called by muse, mutect2
- PRKAG3 | c.143G>C p.R48T | Missense Mutation (SNP) | VAF 58/437 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.111); catalogued as COSV52103716, COSV52103936; called by muse, mutect2, varscan2
- PXDNL | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 27/299 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100684251, COSV62478353; called by muse, mutect2
- SHCBP1L | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 46/464 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs757649009, COSV62353893; called by muse, mutect2
- SIGLEC14 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 58/768 reads (8%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.587); catalogued as rs753560578, COSV55777551, COSV55779228; called by muse, mutect2
- TMEM151B | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 49/355 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1445302149; called by muse, mutect2, varscan2
- TNIP3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.36); catalogued as rs746782978, COSV50246703; called by muse, mutect2, varscan2
- TNR | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 51/477 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs138654492; called by muse, mutect2, varscan2
- UNC79 | c.5780G>A p.R1927Q (on ENST00000393151 / NM_001346218.2; = p.R1750Q on NM_020818.5) | Missense Mutation (SNP) | VAF 87/502 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs770522803, COSV56383061; called by muse, mutect2, varscan2
- CNNM4 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 72/616 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COBL | c.2966T>C p.V989A | Missense Mutation (SNP) | VAF 55/454 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- DHX37 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FNDC1 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 64/660 reads (10%) | called by muse, mutect2
- KALRN | c.3979C>T p.H1327Y | Missense Mutation (SNP) | VAF 34/371 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2
- LMAN2 | c.46T>C p.C16R | Missense Mutation (SNP) | VAF 103/722 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MUSK | c.2387_2389del p.F796del | In Frame Del (DEL) | VAF 36/342 reads (11%) | called by pindel, varscan2
- NKX6-2 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 102/876 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PNPLA5 | c.83_98del p.T28Sfs*49 | Frame Shift Del (DEL) | VAF 90/777 reads (12%) | called by mutect2, pindel
- RSPH10B2 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 38/357 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SCFD2 | c.155C>G p.P52R | Missense Mutation (SNP) | VAF 68/476 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SDK1 | c.3892A>G p.T1298A | Missense Mutation (SNP) | VAF 45/404 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3TC2 | c.2720G>A p.C907Y | Missense Mutation (SNP) | VAF 50/447 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SHCBP1L | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRPK2 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TTN | c.18168G>C p.E6056D (on ENST00000591111; = p.E5129D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/325 reads (13%) | PolyPhen benign (0.03); called by muse, mutect2, varscan2
- UBXN2B | c.851A>G p.N284S | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.037); called by muse, mutect2
- ABCA13 | c.12135C>T p.A4045= | Silent (SNP) | VAF 54/513 reads (11%) | catalogued as rs756550869, COSV71293444; called by muse, mutect2, varscan2
- CACNB4 | c.1191G>A p.A397= | Silent (SNP) | VAF 45/390 reads (12%) | catalogued as rs369276166; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- CEP295NL | c.156C>T p.F52= | Silent (SNP) | VAF 59/465 reads (13%) | catalogued as rs937177060; called by muse, mutect2, varscan2
- CYP1A1 | c.858T>C p.I286= | Silent (SNP) | VAF 34/311 reads (11%) | called by muse, mutect2, varscan2
- DCLK3 | c.225C>T p.H75= | Silent (SNP) | VAF 34/560 reads (6%) | called by muse, mutect2
- DYNC2I2 | c.81G>T p.A27= | Silent (SNP) | VAF 93/572 reads (16%) | catalogued as rs769249867; called by muse, mutect2, varscan2
- FOXI2 | c.99C>T p.G33= | Silent (SNP) | VAF 89/749 reads (12%) | called by muse, mutect2, varscan2
- GRIP1 | c.879C>T p.G293= | Silent (SNP) | VAF 26/245 reads (11%) | catalogued as rs746461059, COSV54017194; called by muse, mutect2, varscan2
- GRM6 | c.816C>T p.N272= | Silent (SNP) | VAF 39/497 reads (8%) | catalogued as rs1046529474, COSV51441167; called by muse, mutect2
- HERC1 | c.10176G>A p.V3392= | Silent (SNP) | VAF 59/475 reads (12%) | catalogued as rs761597330; called by muse, mutect2, varscan2
- LHX5 | c.1044G>A p.P348= | Silent (SNP) | VAF 73/569 reads (13%) | called by muse, mutect2, varscan2
- LRP2 | c.13854G>A p.S4618= | Silent (SNP) | VAF 41/468 reads (9%) | catalogued as rs756813419; called by muse, mutect2
- NPHP4 | c.2358C>T p.V786= | Silent (SNP) | VAF 47/422 reads (11%) | catalogued as rs371647995; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP4R4 | c.1830T>C p.A610= | Silent (SNP) | VAF 21/276 reads (8%) | called by muse, mutect2
- ROBO4 | c.909C>T p.A303= | Silent (SNP) | VAF 87/685 reads (13%) | catalogued as rs572632935; called by muse, mutect2, varscan2
- SHE | c.285C>A p.G95= | Silent (SNP) | VAF 98/788 reads (12%) | called by muse, mutect2, varscan2
- USP24 | c.1665C>T p.L555= | Silent (SNP) | VAF 24/264 reads (9%) | catalogued as COSV53774523; called by muse, mutect2, varscan2
- DNAJB6 | c.691+9C>A | Intron (SNP) | VAF 26/618 reads (4%) | called by muse, mutect2
- KCNAB2 | c.1014+60C>T | Intron (SNP) | VAF 60/604 reads (10%) | called by muse, mutect2
- MUCL3 | c.946+245A>G | Intron (SNP) | VAF 73/613 reads (12%) | called by muse, mutect2, varscan2
- PLEKHG4B | chr5:139560 G>A | 5'Flank (SNP) | VAF 49/516 reads (9%) | catalogued as rs761612717; called by muse, mutect2, varscan2
